CGCI case BLGSP-71-30-00669 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1a9b51ca-3540-4249-847e-87882b37138e

Demographics
Sex at birth: male; Age at index: 55 years; Vital status: Dead; Days to death: 218 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Lymph nodes of head, face and neck; Classification of tumor: primary; Age at diagnosis: 55.5 years (20,289 days); Year of diagnosis: 2011; Method of diagnosis: Excisional Biopsy; Ann Arbor pathologic stage: Stage II; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 189 days; Ann Arbor extranodal involvement: Yes; Burkitt lymphoma clinical variant: Sporadic, adult; Max tumor bulk site: Thyroid; Sites of involvement: Thyroid.
   Pathology details: Bone marrow malignant cells: No; Lymph node involved site: Cervical, NOS; Lymph nodes positive: 1; Lymph nodes tested: 1; Tumor largest dimension diameter: 13 cm.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Regimen or line of therapy: R-CODOX-M; Days to treatment start: 3 days; Days to treatment end: 166 days; Number of cycles: 4; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Regimen or line of therapy: R-CHOP; Days to treatment start: 3 days; Days to treatment end: 166 days; Number of cycles: 4; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin + Methotrexate + Prednisone + Rituximab + Vincristine; Initial disease status: Initial Diagnosis; Days to treatment start: 3 days; Days to treatment end: 166 days; Number of cycles: 4; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Progressive Disease.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 0 days; ECOG performance status: 4.
- Days to follow up: 189 days; Disease response: With Tumor.

Molecular and laboratory tests
- BCL2 (FISH): Normal.
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC translocation (FISH): Abnormal, NOS.
- MYC translocation (FISH): Positive.
- Epstein-Barr Virus (ISH): Negative.
- Lactate Dehydrogenase 328 [Blood test normal range upper: 240].

Other clinical attributes
- Day 0: Weight: 115 kg; Height: 185 cm; BMI: 33.6.

Biospecimens (3 samples)
- Sample BLGSP-71-30-00669-01A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node(s) Cervical; Preservation method: FFPE; Days to sample procurement: 0 days; Method of sample procurement: Excisional Biopsy; Tissue collection type: Retrospective.
- Sample BLGSP-71-30-00669-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Biospecimen anatomic site: Lymph Node.
- Sample BLGSP-71-30-00669-01Z: Sample type: Tumor; Tissue type: Tumor.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), classic morphology; Extranodal site involvement: 1; Lymph nodes examined: Yes; Other pos node location: cervical.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: cervical.
- Primary pathology, Pos lymph node locations: Pos lymph node location: Other Location, specify.
- Stage record, Ann arbor: B symptoms present indicator: Yes.
- Tests performed: LDH level: 328; Immunophenotypic analysis method: Immunohistochemistry; Ebv status malignan cells method: EBER in situ hybridization.
- Tests performed, Genetic testing results, Genetic testing result 1: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 4: Immunophenotypic analysis tested: BCL2.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 1: Genetic abnormality tested: C-myc.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 3: Genetic abnormality tested: BCL2.
- Treatments, Treatment: Therapy regimen: Initial; Chemo end reporting period: Yes; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharmaceutical regimen other: Cyclophosphamide (x1), CODOXMR (x1), CHOPR (x3); Pharma adjuvant cycles count: 4; Treatment best response: Clinical Progressive Disease.

Additional fields from the CGCI biospecimen supplement workbook CGCI-BLGSP_biospecimenSupplementSpreadsheet_TWIST_20220304.xlsx (sheet Sheet1), for sample BLGSP-71-30-00669-01A-01E-0001-01:
- % tumour: 80
